HCMI case HCM-EXPT-0928-C50 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/1cbdddb6-af99-4137-9629-2e45e1afb8ca

Demographics
Sex at birth: female; Year of birth: 1977.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 41.9 years (15,300 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0928-C50-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0928-C50-01A-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
  Slide HCM-EXPT-0928-C50-01A-S2-HE: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
